TCGA case TCGA-12-1599 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/165b8f99-f7ba-4553-96ed-235e3f77e19c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Dead; Days to death: 781 days (2.1 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 47.7 years (17,432 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 75 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 59 days; Number of cycles: 1; Treatment dose: 5,880 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Imatinib Mesylate; Initial disease status: Progressive Disease; Days to treatment start: 96 days; Days to treatment end: 127 days; Treatment dose: 30,000 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Initial disease status: Progressive Disease; Days to treatment start: 160 days; Days to treatment end: 391 days (1.1 years); Number of cycles: 7; Treatment dose: 66,750 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Imatinib Mesylate; Initial disease status: Progressive Disease; Days to treatment start: 160 days; Days to treatment end: 391 days (1.1 years); Treatment dose: 90,400 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib; Initial disease status: Progressive Disease; Days to treatment start: 406 days (1.1 years); Days to treatment end: 433 days (1.2 years); Treatment dose: 14,000 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sirolimus; Initial disease status: Progressive Disease; Days to treatment start: 406 days (1.1 years); Days to treatment end: 433 days (1.2 years); Treatment dose: 280 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 438 days (1.2 years); Days to treatment end: 602 days (1.6 years); Treatment dose: 5,520 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Initial disease status: Progressive Disease; Days to treatment start: 461 days (1.3 years); Days to treatment end: 492 days (1.3 years); Number of cycles: 1; Treatment dose: 30,000 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 621 days (1.7 years); Days to treatment end: 671 days (1.8 years); Treatment dose: 1,840 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 621 days (1.7 years); Days to treatment end: 671 days (1.8 years); Number of cycles: 1; Treatment dose: 1,600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 675 days (1.8 years); Days to treatment end: 727 days (2.0 years); Treatment dose: 1,760 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 675 days (1.8 years); Days to treatment end: 727 days (2.0 years); Number of cycles: 1; Treatment dose: 5,300 mg; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 48.0 years (17,521 days); Days to diagnosis: 89 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 89 (post initial treatment): Progression or recurrence: Yes; Days to progression: 89 days.
- Days to follow up: 769 days (2.1 years); Disease response: With Tumor.
- Days to follow up: 781 days (2.1 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-1599-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-12-1599-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-12-1599-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 5.
- Sample TCGA-12-1599-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-1599-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 5: Pharmaceutical therapy drug name: Gleevac.
- Drug treatment 6: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 10: Pharmaceutical therapy drug name: CPT 11.
- Drug treatment 10, Route of administrations: Route of administration: IV.
- Drug treatment 11: Pharmaceutical therapy drug name: Temodar.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 781 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 781 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 89 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-1599-01A-01D-0591-01): tumor purity 0.7, ploidy 2.01, whole-genome doublings 0.
